Gene-level copy-number profile of tumor specimen ALCH-B5FY-TTP1-A from ALCHEMIST case ALCH-B5FY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,153 days).
Specimen ALCH-B5FY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8593700-ee34-4ea7-891b-f4d882186339.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B5FY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/c6ef5579-f110-44ba-914a-2b94813e0f13

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 4,021; copy number 2: 54,458; copy number 3: 328; copy number 4: 16; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,454,665–3,487,627, 2 genes: ARHGEF16, AL512413.1.
- chr1:16,467,436–16,499,257, 1 gene (within-gene range 0–2): CROCCP3.
- chr1:43,991,500–44,031,467, 1 gene (within-gene range 0–2): SLC6A9.
- chr2:241,849,884–241,873,823, 2 genes: PDCD1, RTP5.
- chr4:8,182,072–8,241,803, 1 gene: SH3TC1.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr9:132,161,676–132,244,526, 1 gene: NTNG2.
- chr11:63,974,620–63,988,346, 2 genes (within-gene range 0–2): COX8A, AP000721.1.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr15:25,180,497–25,215,622, 20 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr15:25,232,387–25,243,695, 7 genes (within-gene range 0–2): SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr17:142,789–386,254, 5 genes (within-gene range 0–2): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1.
- chr17:2,375,061–2,401,104, 3 genes (within-gene range 0–2): AC006435.2, MNT, AC006435.1.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–2): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr17:29,071,122–29,180,398, 3 genes (within-gene range 0–2): MYO18A, TIAF1, AC024619.3.
- chr17:42,647,834–42,683,917, 6 genes (within-gene range 0–2): ATP5MGP7, HMGB3P27, TUBG2, PLEKHH3, CCR10, AC100793.2.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr22:20,148,416–20,151,055, 1 gene: CCDC188.
- chr22:21,919,425–21,982,813, 3 genes: PPM1F, PPM1F-AS1, TOP3B.
- chr22:49,612,657–49,615,716, 1 gene (within-gene range 0–1): Z97192.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,520,729–231,566,524, 2 genes, copy number 5 (within-gene range 2–5): AL445524.1, TSNAX.

Autosomal genes at a single copy (total copy number 1): 1,192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
